Gene-level copy-number profile of tumor specimen HCM-BROD-1078-C49-06B from HCMI case HCM-BROD-1078-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 45.9 years (16,769 days).
Specimen HCM-BROD-1078-C49-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e04978fa-7d7e-47c8-bfac-b4a7250715dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1078-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/637d4005-4099-41d1-bd75-11e1ef679836

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 8,069; copy number 2: 46,484; copy number 3: 3,216; copy number 4: 94; copy number 5: 437; copy number 6: 15; copy number 7: 36; copy number 10: 7.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:75,037,836–75,431,588, 19 genes (within-gene range 0–1): DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,451,725, 1 gene (within-gene range 0–1): AC010997.6.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr21:9,053,122–9,129,752, 4 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 495 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:84,290,683–85,332,996, 22 genes, copy number 6–7: FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA.
- chr2:86,020,216–87,076,429, 29 genes, copy number 7–10 (within-gene range 7–13): POLR1A, PTCD3, SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35, REEP1, U8, AC009408.1, KDM3A, CHMP3, RNF103-CHMP3, RNU6-640P, AC015971.1, RNF103, RMND5A, CD8A, CD8B, ANAPC1P1, AC111200.1, RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1.
- chr13:39,655,627–40,535,807, 11 genes, copy number 5 (within-gene range 1–5): COG6, MIR4305, RNY4P14, CDKN2AIPNLP3, AZU1P1, SNORD116, LINC00598, LINC00332, RPL17P51, RNY3P9, RN7SKP2.
- chr17:10,383,132–22,056,755, 429 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr17:22,606,388–22,706,703, 4 genes, copy number 5: AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Autosomal genes at a single copy (total copy number 1): 6,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
